FM case AD16746 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/b5f00bb2-028f-4986-a15f-1bd4fd94068a

Female, 56.8 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); metastasis biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
